FM case AD4428 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Trachea.
https://portal.gdc.cancer.gov/cases/b7fd3e84-e277-4586-8317-2453b9c2513b

Male, 48.5 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the trachea; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
